Somatic mutation profile of tumor specimen MP2PRT-PANZUI-TMP1-A (aliquot MP2PRT-PANZUI-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANZUI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 8.6 years (3,136 days).
Specimen MP2PRT-PANZUI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56c7b8ba-e601-4938-8366-fbaf7785fd7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZUI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZUI-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f981b7-705b-45d5-92b8-addcf7868139

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 5, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs772160289, COSV61626940; called by muse, mutect2, varscan2
- FAN1 | c.2264del p.E755Gfs*23 | Frame Shift Del (DEL) | VAF 151/384 reads (39%) | catalogued as rs756840415, COSV62951220; called by mutect2, pindel*, varscan2
- GALE | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs779150200; called by muse, mutect2, varscan2
- MYC | c.757G>A p.E253K (on ENST00000377970; = p.E268K on NM_002467.6) | Missense Mutation (SNP) | VAF 319/322 reads (99%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV52368855; called by muse, mutect2, varscan2
- SETD2 | c.4775G>A p.R1592Q | Missense Mutation (SNP) | VAF 141/277 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57439624, COSV57447701; called by muse, mutect2, varscan2
- SNX17 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 166/335 reads (50%) | catalogued as rs777906560; called by muse, mutect2, varscan2
- DIP2C | c.4155T>A p.Y1385* | Nonsense Mutation (SNP) | VAF 142/309 reads (46%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.332_333delinsCTCC p.Y111Sfs*? | Frame Shift Ins (INS) | VAF 18/31 reads (58%) | called by pindel, varscan2*
- IMPG1 | c.848T>A p.I283N | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR17 | c.1030del p.S344Afs*9 | Frame Shift Del (DEL) | VAF 98/357 reads (27%) | called by mutect2, pindel, varscan2
- AVEN | c.753C>T p.C251= | Silent (SNP) | VAF 22/409 reads (5%) | catalogued as rs370527932; called by muse, mutect2
- BOD1L1 | c.78G>A p.P26= | Silent (SNP) | VAF 9/284 reads (3%) | catalogued as rs1223923940; called by muse, mutect2
- DPYSL3 | c.72C>T p.G24= | Silent (SNP) | VAF 249/474 reads (53%) | called by muse, mutect2, varscan2
- KCNB2 | c.1449C>T p.D483= | Silent (SNP) | VAF 151/306 reads (49%) | catalogued as rs555669570, COSV73051774; called by muse, mutect2, varscan2
- LMAN1 | c.1104G>A p.E368= | Silent (SNP) | VAF 170/329 reads (52%) | called by muse, mutect2, varscan2
- ODF1 | c.87C>T p.D29= | Silent (SNP) | VAF 258/271 reads (95%) | catalogued as rs369351331; called by muse, mutect2, varscan2
- ZNF474 | c.192G>T p.G64= | Silent (SNP) | VAF 147/309 reads (48%) | catalogued as COSV56946643; called by muse, mutect2, varscan2
- MLLT10 | c.240+17911C>T | Intron (SNP) | VAF 187/397 reads (47%) | catalogued as rs1401136355; called by muse, mutect2, varscan2
